Somatic mutation profile of tumor specimen 0DHHL9 from CCDI case PBBUCE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (203 days).
Specimen 0DHHL9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41060af-b2ae-464b-bcca-18be289b83a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHHJ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01ed6440-79d8-493a-9f62-7dd859f3cf3f

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN3 | c.664C>T p.R222C (on ENST00000557594 / NM_001272020.2; = p.R854C on NM_004796.6) | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs747277637, COSV55315618; called by muse, varscan2
- CD180 | c.680T>C p.L227S | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CD180 | c.681G>A p.L227= | Silent (SNP) | VAF 26/218 reads (12%) | catalogued as rs1192077978, COSV56518622; called by muse, varscan2
- ATP1B2 | c.*1497A>G | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, varscan2
